Somatic mutation profile of tumor specimen C3L-07069-04 (aliquot CPT0540090009) from CPTAC case C3L-07069, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 71.8 years (26,226 days).
Specimen C3L-07069-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d8fc81d-ad54-4b9f-a5e7-b06319454357.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07069-32 (Blood Derived Normal), aliquot CPT0540210004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b48a78e8-a911-4a30-8528-306e60359679

The open-access MAF lists 1,594 somatic variants for this specimen: 1,204 protein-altering or splice-affecting, 338 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 881, Silent 338, Frame Shift Del 214, Frame Shift Ins 40, Intron 38, Nonsense Mutation 34, In Frame Del 15, Splice Region 9, Splice Site 6, 3'UTR 6, 5'Flank 4, Translation Start Site 3.

Variants (750 of 1,594; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 121/526 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72653768, CM062375, COSV52747038; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.2506C>T p.R836* | Nonsense Mutation (SNP) | VAF 99/439 reads (23%) | catalogued as rs72559722, CM001605, COSV56849386; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.1113del p.Q372Sfs*19 | Frame Shift Del (DEL) | VAF 104/496 reads (21%) | catalogued as rs875989848; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CFAP410 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 80/380 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs763821454, COSV57394362; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL2A1 | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 75/322 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs121912882, CM980396, COSV61528961; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.2054G>A p.R685H (on ENST00000460911 / NM_001203247.2; = p.R690H on NM_004456.5) | Missense Mutation (SNP) | VAF 57/329 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1554481435, COSV57446082; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 74/320 reads (23%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- GABRG2 | c.889G>A p.G297R (on ENST00000361925 / NM_001375343.1; = p.G257R on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs1554098235, CM155068, COSV100729751, COSV62721042; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 87/397 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as CM002273, COSV55670863; called by muse, mutect2, varscan2
- GNS | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 66/330 reads (20%) | catalogued as rs119461974, CM030467, COSV50697172; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFIX | c.303del p.C102Afs*33 | Frame Shift Del (DEL) | VAF 131/655 reads (20%) | catalogued as rs886041304, COSV99063154; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TREX1 | c.144del p.T49Pfs*16 (on ENST00000625293 / NM_033629.6; = p.T39Pfs*16 on NM_007248.5) | Frame Shift Del (DEL) | VAF 133/609 reads (22%) | catalogued as rs748914604; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- AAR2 | c.397T>G p.W133G | Missense Mutation (SNP) | VAF 96/516 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349214878; called by muse, mutect2, varscan2
- ABCA9 | c.3954dup p.G1319Rfs*2 | Frame Shift Ins (INS) | VAF 35/131 reads (27%) | catalogued as rs756170862; called by mutect2, pindel, varscan2
- ABCB9 | c.1975C>T p.R659W (on ENST00000280560 / NM_019625.4; = p.R616W on NM_019624.3) | Missense Mutation (SNP) | VAF 132/541 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774362505, COSV54890681; called by muse, mutect2, varscan2
- ABCG1 | c.115A>G p.S39G | Missense Mutation (SNP) | VAF 97/394 reads (25%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs747843145; called by muse, mutect2, varscan2
- AC244197.3 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 77/395 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.249); catalogued as rs370125505, COSV100558049; called by muse, mutect2, varscan2
- ACSM6 | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 59/384 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1215341635; called by muse, mutect2, varscan2
- ADAD2 | c.581G>A p.R194Q (on ENST00000315906 / NM_001145400.2; = p.R266Q on NM_139174.4) | Missense Mutation (SNP) | VAF 133/558 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774543669, COSV99235190; called by muse, mutect2, varscan2
- ADAMTS10 | c.976G>A p.G326S | Missense Mutation (SNP) | VAF 82/448 reads (18%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.943); catalogued as rs373603462; called by muse, mutect2, varscan2
- ADAMTS5 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 131/480 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs759375195, COSV53176118; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 46/249 reads (18%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGB | c.3247C>T p.R1083C | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1274771179; called by muse, mutect2, varscan2
- ADGRB2 | c.764del p.G255Afs*23 | Frame Shift Del (DEL) | VAF 112/510 reads (22%) | catalogued as COSV57072226; called by mutect2, pindel, varscan2
- ADGRD2 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 91/500 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs1312266889; called by muse, mutect2, varscan2
- ADGRF4 | c.245del p.K82Sfs*29 | Frame Shift Del (DEL) | VAF 54/246 reads (22%) | catalogued as rs764604854; called by mutect2, varscan2
- AFF1 | c.1873A>G p.R625G | Missense Mutation (SNP) | VAF 106/455 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs774462481; called by muse, mutect2, varscan2
- AFF2 | c.3884G>A p.R1295H | Missense Mutation (SNP) | VAF 92/403 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs782318095, COSV53980006; called by muse, mutect2, varscan2
- AKTIP | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 64/270 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs781311887, COSV50886811; called by muse, mutect2, varscan2
- AL592490.1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 56/652 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV101308198, COSV69424549; called by muse, mutect2
- ALAS1 | c.361A>C p.S121R | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1559872199; called by muse, mutect2
- ALMS1 | c.8006G>A p.R2669Q | Missense Mutation (SNP) | VAF 63/356 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs747268891, COSV52506111; called by muse, mutect2, varscan2
- ALOX12 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 148/628 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.583); catalogued as rs536359047; called by muse, mutect2
- AMZ1 | c.637dup p.E213Gfs*11 | Frame Shift Ins (INS) | VAF 117/707 reads (17%) | catalogued as rs1162050338; called by mutect2, pindel, varscan2
- ANKH | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 40/510 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs1185614384; called by muse, mutect2
- ANKMY1 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 109/456 reads (24%) | catalogued as rs201141473; called by muse, mutect2, varscan2
- ANKRD12 | c.2169del p.K723Nfs*45 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as rs1469889281; called by mutect2, varscan2
- ANKRD30A | c.2930T>G p.L977R (on ENST00000611781; = p.L921R on NM_052997.2) | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV64615413; called by muse, mutect2
- ANXA13 | c.451del p.I151Sfs*20 | Frame Shift Del (DEL) | VAF 33/188 reads (18%) | catalogued as rs759218332; called by mutect2, varscan2
- AP4B1 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 86/374 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs763842373, COSV56725261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APEH | c.1528C>G p.P510A | Missense Mutation (SNP) | VAF 104/411 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56535366; called by muse, mutect2, varscan2
- ARID1B | c.5974del p.V1992Wfs*16 | Frame Shift Del (DEL) | VAF 112/532 reads (21%) | catalogued as rs749055122; called by mutect2, pindel, varscan2
- ARMC12 | c.790G>A p.A264T (on ENST00000373866 / NM_001286574.2; = p.A291T on NM_145028.5) | Missense Mutation (SNP) | VAF 72/448 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs200490512; called by muse, mutect2, varscan2
- ARMC7 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 148/540 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs142697875; called by muse, mutect2, varscan2
- ARSD | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 150/571 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs374011265, COSV66973600; called by muse, mutect2
- ARVCF | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 92/389 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs753809266, COSV54268964; called by muse, mutect2, varscan2
- ATG10 | c.483del p.F161Lfs*12 | Frame Shift Del (DEL) | VAF 28/177 reads (16%) | catalogued as rs1186430519; called by mutect2, pindel, varscan2
- ATP13A2 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 115/448 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs774684946, COSV100454438; called by muse, varscan2
- ATP23 | c.121T>C p.F41L | Missense Mutation (SNP) | VAF 126/516 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55686479; called by muse, varscan2
- AVP | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 142/776 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1363312021; called by muse, varscan2
- B4GALNT4 | c.918del p.R307Vfs*100 | Frame Shift Del (DEL) | VAF 128/570 reads (22%) | catalogued as rs770737105, COSV57327371; called by mutect2, pindel, varscan2
- BCKDK | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 52/312 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.174); catalogued as rs1185957277, COSV54892917; called by muse, varscan2
- BCORL1 | c.3842A>G p.H1281R | Missense Mutation (SNP) | VAF 149/694 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as rs939681879; called by muse, mutect2, varscan2
- BECN1 | c.1068del p.L357Cfs*77 | Frame Shift Del (DEL) | VAF 72/360 reads (20%) | catalogued as rs1395644174; called by mutect2, pindel, varscan2
- BICRA | c.2935dup p.A979Gfs*86 | Frame Shift Ins (INS) | VAF 129/532 reads (24%) | catalogued as rs756990560; called by mutect2, varscan2
- BMP2 | c.1139T>C p.V380A | Missense Mutation (SNP) | VAF 62/287 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66578558; called by muse, mutect2, varscan2
- BPIFB4 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 131/645 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759796722, COSV64951256; called by muse, mutect2, varscan2
- BPTF | c.863T>C p.V288A | Missense Mutation (SNP) | VAF 98/404 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV58847774; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 22/137 reads (16%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BSN | c.6091C>T p.R2031C | Missense Mutation (SNP) | VAF 102/466 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.333); catalogued as rs759981264, COSV56522180; called by muse, mutect2, varscan2
- BUD23 | c.766_768del p.K256del | In Frame Del (DEL) | VAF 181/443 reads (41%) | catalogued as rs1246062269; called by pindel, varscan2
- C1S | c.842del p.K281Rfs*39 | Frame Shift Del (DEL) | VAF 66/295 reads (22%) | catalogued as rs781818365; called by mutect2, pindel, varscan2
- C2CD5 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs747737504, COSV61722835, COSV61723120; called by muse, mutect2, varscan2
- C2orf73 | c.309del p.F103Lfs*17 | Frame Shift Del (DEL) | VAF 67/309 reads (22%) | catalogued as rs747496393; called by mutect2, pindel, varscan2
- C4orf48 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 160/668 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs1560927568, COSV101247745; called by muse, varscan2
- C7orf26 | c.914T>C p.L305P | Missense Mutation (SNP) | VAF 133/645 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs751676254; called by muse, mutect2, varscan2
- C7orf31 | c.358del p.S120Vfs*9 | Frame Shift Del (DEL) | VAF 60/142 reads (42%) | catalogued as rs750735753; called by mutect2, varscan2
- C7orf50 | c.215del p.K72Rfs*87 | Frame Shift Del (DEL) | VAF 119/690 reads (17%) | catalogued as COSV62475944; called by mutect2, pindel, varscan2
- CACNA1E | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 104/369 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs757890592, COSV62383300; called by muse, mutect2, varscan2
- CAPN15 | c.388_390del p.E130del | In Frame Del (DEL) | VAF 126/590 reads (21%) | catalogued as rs1410078492; called by pindel, varscan2
- CASP1 | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 103/447 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.617); catalogued as COSV100782740; called by muse, mutect2, varscan2
- CAVIN2 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 77/329 reads (23%) | catalogued as COSV58424663; called by muse, mutect2, varscan2
- CAVIN3 | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 146/614 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.475); catalogued as COSV58268585; called by muse, mutect2, varscan2
- CBARP | c.16A>G p.T6A (on ENST00000382477; = p.T12A on NM_152769.3) | Missense Mutation (SNP) | VAF 154/626 reads (25%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs143196649; called by muse, varscan2
- CCDC120 | c.1486A>G p.S496G | Missense Mutation (SNP) | VAF 143/720 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs904044618; called by muse, mutect2, varscan2
- CCDC136 | c.97C>G p.Q33E | Missense Mutation (SNP) | VAF 96/593 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as rs757044539; called by muse, mutect2, varscan2
- CCDC197 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 83/356 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs958254298; called by muse, mutect2, varscan2
- CCDC38 | c.1686del p.F562Lfs*4 | Frame Shift Del (DEL) | VAF 26/121 reads (21%) | catalogued as rs769501825; called by mutect2, pindel, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC88A | c.2335del p.I779Sfs*4 | Frame Shift Del (DEL) | VAF 17/166 reads (10%) | catalogued as COSV55059558; called by mutect2, pindel, varscan2
- CCDC9B | c.609del p.T204Rfs*44 | Frame Shift Del (DEL) | VAF 87/437 reads (20%) | catalogued as rs772754432; called by mutect2, pindel, varscan2
- CCER1 | c.1154A>C p.N385T | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100726911; called by muse, mutect2, varscan2
- CCNE2 | c.124del p.R42Efs*38 | Frame Shift Del (DEL) | VAF 42/224 reads (19%) | catalogued as rs1563685429; called by mutect2, pindel, varscan2
- CCT3 | c.1135dup p.A379Gfs*2 | Frame Shift Ins (INS) | VAF 61/317 reads (19%) | catalogued as rs1195962947; called by mutect2, pindel, varscan2
- CD109 | c.779T>C p.V260A | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs757371111; called by muse, mutect2, varscan2
- CD59 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs763958932; called by muse, mutect2, varscan2
- CD6 | c.154A>C p.S52R | Missense Mutation (SNP) | VAF 66/540 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV57836473; called by muse, mutect2, varscan2
- CDC42EP1 | c.289del p.R97Gfs*115 | Frame Shift Del (DEL) | VAF 167/691 reads (24%) | catalogued as rs762035931; called by mutect2, pindel, varscan2
- CDH12 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 42/270 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748362589, COSV66444729; called by muse, mutect2, varscan2
- CDH7 | c.1634C>T p.T545I | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs767286671; called by muse, mutect2, varscan2
- CDK2AP1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs866585401; called by muse, varscan2
- CDSN | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 178/820 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.019); catalogued as rs560607707, COSV99457015; called by muse, mutect2
- CELSR2 | c.4109G>A p.R1370H | Missense Mutation (SNP) | VAF 152/522 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777025303, COSV99603519; called by muse, mutect2, varscan2
- CFAP161 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as rs749821239, COSV54429461; called by muse, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 26/104 reads (25%) | catalogued as rs751492244; called by mutect2, varscan2
- CHAF1A | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 73/286 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1469672102, COSV56672697, COSV56675807; called by muse, mutect2, varscan2
- CHD4 | c.2335C>T p.R779W (on ENST00000357008 / NM_001363606.2; = p.R792W on NM_001273.5) | Missense Mutation (SNP) | VAF 124/501 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58901404; called by muse, mutect2, varscan2
- CHRM3 | c.1377G>T p.K459N | Missense Mutation (SNP) | VAF 95/347 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs1407655504; called by muse, mutect2, varscan2
- CIP2A | c.2087A>G p.Q696R | Missense Mutation (SNP) | VAF 80/304 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.813); catalogued as rs1559689477; called by muse, mutect2, varscan2
- CLASP1 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 72/355 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1400137238, COSV55326231; called by muse, mutect2, varscan2
- CLCF1 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 82/403 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs145294376; called by muse, mutect2, varscan2
- CLSTN2 | c.2521G>A p.V841M | Missense Mutation (SNP) | VAF 76/430 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs762384117, COSV101515955; called by muse, mutect2
- CNNM4 | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 104/461 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs769185337, COSV65660393, COSV65661394; called by muse, mutect2, varscan2
- CNOT1 | c.2706del p.Q904Sfs*9 | Frame Shift Del (DEL) | VAF 42/264 reads (16%) | catalogued as rs1397135931, COSV55313852; called by mutect2, pindel, varscan2
- CNTNAP3 | c.2268G>T p.K756N | Missense Mutation (SNP) | VAF 51/344 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99904004; called by muse, mutect2, varscan2
- CNTNAP4 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as COSV56693831; called by muse, varscan2
- COL13A1 | c.668G>A p.S223N | Missense Mutation (SNP) | VAF 99/483 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.074); catalogued as rs1335888017; called by muse, mutect2, varscan2
- COL17A1 | c.4051G>A p.A1351T | Missense Mutation (SNP) | VAF 138/668 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs1482699547; called by muse, mutect2, varscan2
- COL18A1 | c.299C>G p.P100R | Missense Mutation (SNP) | VAF 133/575 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.268); catalogued as COSV100701016; called by muse, mutect2, varscan2
- COL3A1 | c.3082C>T p.P1028S | Missense Mutation (SNP) | VAF 61/285 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.651); catalogued as COSV58587036; called by muse, mutect2, varscan2
- COL4A6 | c.946C>A p.Q316K | Missense Mutation (SNP) | VAF 65/295 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57859710; called by muse, mutect2, varscan2
- COL5A3 | c.2999del p.P1000Qfs*144 | Frame Shift Del (DEL) | VAF 86/350 reads (25%) | catalogued as rs760926657; called by mutect2, pindel, varscan2
- COL7A1 | c.4097G>A p.R1366Q | Missense Mutation (SNP) | VAF 110/446 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs760759581, COSV60390779; called by muse, mutect2, varscan2
- CPT2 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 89/372 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs794727616; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRIP2 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 108/418 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as rs868956518; called by muse, mutect2, varscan2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 49/165 reads (30%) | catalogued as rs756999481; called by mutect2, pindel, varscan2
- CSNK1D | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 83/315 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53923516; called by muse, mutect2, varscan2
- CSNK1E | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 91/402 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1187975483; called by muse, mutect2, varscan2
- CSPP1 | c.475C>T p.R159W (on ENST00000676605; = p.R118W on NM_024790.6) | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1024300760, COSV51582107; called by muse, mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 48/330 reads (15%) | catalogued as rs756924682; called by mutect2, varscan2
- CSTF1 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 14/463 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs1431453883; called by muse, mutect2
- CTNND2 | c.1367G>A p.S456N | Missense Mutation (SNP) | VAF 57/304 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV58908549; called by muse, mutect2, varscan2
- CTU2 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 108/414 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs778284872; called by muse, mutect2, varscan2
- CUBN | c.7798G>A p.E2600K | Missense Mutation (SNP) | VAF 80/381 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); catalogued as rs766806038, COSV64710921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CXCL8 | c.*5del | Frame Shift Del (DEL) | VAF 37/156 reads (24%) | catalogued as rs201169323; called by mutect2, pindel, varscan2
- DAGLB | c.1156C>A p.L386M | Missense Mutation (SNP) | VAF 71/438 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); catalogued as rs376696645; called by muse, mutect2, varscan2
- DDB1 | c.512A>G p.Y171C | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs930007745, COSV57100860; called by muse, mutect2, varscan2
- DEAF1 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs1308362441, COSV58609358; called by muse, varscan2
- DENND3 | c.3127C>T p.R1043C | Missense Mutation (SNP) | VAF 93/424 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs775372766, COSV52808671; called by muse, mutect2, varscan2
- DGKB | c.2362del p.T788Pfs*25 | Frame Shift Del (DEL) | VAF 72/411 reads (18%) | catalogued as COSV99342353; called by pindel, varscan2
- DHRS9 | c.669del p.K223Nfs*25 | Frame Shift Del (DEL) | VAF 69/333 reads (21%) | catalogued as rs756920263; called by mutect2, varscan2
- DHX16 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 152/562 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as rs1328140113; called by muse, mutect2, varscan2
- DIS3L | c.2426G>A p.R809H (on ENST00000319212 / NM_001143688.3; = p.R726H on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772589174, COSV59914181; called by muse, mutect2, varscan2
- DLG2 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 56/299 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54631130, COSV99714552; called by muse, mutect2, varscan2
- DNAH6 | c.340dup p.S114Kfs*11 | Frame Shift Ins (INS) | VAF 32/154 reads (21%) | catalogued as rs1332983451; called by mutect2, varscan2
- DNMT1 | c.3184G>A p.V1062M | Missense Mutation (SNP) | VAF 125/542 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs560179619, COSV61580914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK7 | c.2603G>T p.G868V | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV52010148; called by mutect2, varscan2
- DPP10 | c.2189T>C p.V730A | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs922931842; called by muse, mutect2, varscan2
- DTHD1 | c.1268G>T p.R423L (on ENST00000456874; = p.R258L on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV62630801; called by muse, mutect2, varscan2
- DTX1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 153/657 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57498759; called by muse, mutect2, varscan2
- ECH1 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 104/445 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as rs1220445627; called by muse, mutect2, varscan2
- EDC4 | c.2975G>A p.R992H | Missense Mutation (SNP) | VAF 102/419 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs374187596; called by muse, mutect2, varscan2
- EDNRA | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60096468; called by muse, mutect2, varscan2
- EEF2 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 92/447 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV100501056; called by muse, mutect2, varscan2
- EFNB3 | c.13del p.H5Ifs*54 | Frame Shift Del (DEL) | VAF 83/387 reads (21%) | catalogued as rs745309220; called by mutect2, pindel, varscan2
- EHD4 | c.368del p.K123Sfs*14 | Frame Shift Del (DEL) | VAF 110/452 reads (24%) | catalogued as rs763598850; called by mutect2, pindel, varscan2
- EHMT1 | c.3734G>A p.R1245H | Missense Mutation (SNP) | VAF 83/456 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.059); catalogued as COSV66044721; called by muse, mutect2, varscan2
- EIPR1 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376371713; called by muse, mutect2, varscan2
- ELAPOR2 | c.2588G>A p.C863Y (on ENST00000450689 / NM_001142749.3; = p.C696Y on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 148/298 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553991387, COSV51885660; called by muse, mutect2, varscan2
- ELF3 | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 127/426 reads (30%) | catalogued as rs1359638271; called by muse, mutect2, varscan2
- ELOA2 | c.671G>A p.S224N | Missense Mutation (SNP) | VAF 116/489 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.142); catalogued as COSV99795799; called by muse, mutect2, varscan2
- EMC9 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs201407803; called by muse, mutect2, varscan2
- ENAM | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 71/319 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs564877872; called by muse, mutect2, varscan2
- ENO1 | c.1100T>C p.V367A | Missense Mutation (SNP) | VAF 68/322 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs746317051; called by muse, mutect2, varscan2
- EOGT | c.420G>A p.T140= | Splice Region (SNP) | VAF 60/210 reads (29%) | catalogued as rs748425624; called by muse, mutect2, varscan2
- EP300 | c.6691A>G p.M2231V | Missense Mutation (SNP) | VAF 136/588 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs780235974; called by muse, mutect2, varscan2
- EPB41 | c.1639G>A p.A547T (on ENST00000343067 / NM_001166005.2; = p.A338T on NM_004437.4) | Missense Mutation (SNP) | VAF 69/245 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as rs771612933; called by muse, mutect2, varscan2
- EPDR1 | c.332A>G p.K111R | Missense Mutation (SNP) | VAF 75/384 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as COSV52257918; called by muse, mutect2, varscan2
- EPPK1 | c.2461G>A p.V821M | Missense Mutation (SNP) | VAF 140/724 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs541428503; called by muse, mutect2, varscan2
- EPS8 | c.2138G>T p.R713L | Missense Mutation (SNP) | VAF 93/393 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV55528992, COSV55533603; called by muse, mutect2, varscan2
- EPS8L2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 125/424 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs369412251; called by muse, mutect2, varscan2
- ERF | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 179/641 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.328); catalogued as rs771103636, COSV99033278; called by muse, mutect2, varscan2
- ERI3 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 107/487 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as rs1045121341; called by muse, mutect2, varscan2
- ERLIN2 | c.797T>C p.M266T | Missense Mutation (SNP) | VAF 94/339 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1176117493; called by muse, mutect2, varscan2
- ESPN | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 164/733 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1394512824; called by muse, mutect2, varscan2
- EVI5L | c.1939C>T p.R647* | Nonsense Mutation (SNP) | VAF 93/330 reads (28%) | catalogued as rs865875167; called by muse, mutect2, varscan2
- EXOG | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as rs142372068; called by muse, mutect2, varscan2
- EZH1 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1220002873, COSV70549716; called by muse, mutect2, varscan2
- FAM185A | c.94T>C p.W32R | Missense Mutation (SNP) | VAF 120/634 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1562837258; called by muse, mutect2, varscan2
- FAM193A | c.2017del p.L673Sfs*142 | Frame Shift Del (DEL) | VAF 159/615 reads (26%) | catalogued as COSV61191975; called by mutect2, varscan2
- FARP1 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 88/491 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748761560; called by muse, mutect2, varscan2
- FBXO11 | c.1295C>T p.A432V (on ENST00000403359 / NM_001190274.2; = p.A348V on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV57016534; called by muse, mutect2, varscan2
- FCHSD2 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 80/365 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs757189973, COSV60815157; called by muse, mutect2, varscan2
- FCRLB | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 107/437 reads (24%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.987); catalogued as COSV61059758; called by muse, mutect2, varscan2
- FEZF2 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 112/445 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51863895; called by muse, mutect2, varscan2
- FGD3 | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 129/623 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751133772, COSV61600270; called by muse, mutect2, varscan2
- FHAD1 | c.3305G>A p.R1102Q | Missense Mutation (SNP) | VAF 105/477 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs992220340; called by muse, mutect2, varscan2
- FLCN | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 59/304 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372304384; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNB | c.3416C>T p.S1139L | Missense Mutation (SNP) | VAF 130/419 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs200677231; called by muse, mutect2, varscan2
- FLOT2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs757325912; called by muse, mutect2, varscan2
- FLT4 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 72/324 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs754733831, COSV56117734; called by muse, mutect2, varscan2
- FMN2 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 116/522 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1403741610; called by muse, mutect2, varscan2
- FOSB | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 149/636 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV62279137; called by muse, mutect2, varscan2
- FOXA3 | c.220_221insA p.L74Hfs*69 | Frame Shift Ins (INS) | VAF 130/660 reads (20%) | catalogued as COSV100141395; called by pindel, varscan2
- FOXE3 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as rs767855430; called by muse, mutect2, varscan2
- FREM1 | c.6097T>C p.C2033R | Missense Mutation (SNP) | VAF 60/365 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs746694579; called by muse, mutect2, varscan2
- FRMPD3 | c.3950C>A p.P1317H | Missense Mutation (SNP) | VAF 127/662 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99346595; called by muse, mutect2, varscan2
- FRZB | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 116/558 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV104400812; called by muse, mutect2, varscan2
- FZD8 | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 116/614 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101020261; called by muse, mutect2, varscan2
- GALK2 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 66/271 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100508651, COSV100509136; called by muse, mutect2, varscan2
- GALNT17 | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 19/661 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61152867; called by muse, mutect2
- GCC2 | c.1820A>G p.H607R | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1426501841; called by muse, mutect2, varscan2
- GDF6 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 106/528 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.251); catalogued as rs984197099, COSV54626496; called by muse, mutect2, varscan2
- GEMIN8 | c.479A>G p.Q160R | Missense Mutation (SNP) | VAF 78/371 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as rs1429936199; called by muse, varscan2
- GGT7 | c.1064G>A p.S355N | Missense Mutation (SNP) | VAF 97/494 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as rs1338904101; called by muse, mutect2, varscan2
- GJB2 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 76/349 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as CD054340, COSV67010791; called by muse, mutect2, varscan2
- GJD4 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 135/638 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1301141931, COSV58702325, COSV58702656; called by muse, mutect2, varscan2
- GLB1 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 65/344 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs774771223, COSV56567888; called by muse, mutect2, varscan2
- GNG12 | c.202dup p.T68Nfs*9 | Frame Shift Ins (INS) | VAF 52/204 reads (25%) | catalogued as rs1022402829; called by mutect2, varscan2
- GOLGA3 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 104/449 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs201755855; called by muse, mutect2, varscan2
- GPATCH2 | c.634del p.R212Efs*3 | Frame Shift Del (DEL) | VAF 55/259 reads (21%) | catalogued as rs945102298; called by mutect2, pindel, varscan2
- GPC1 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 90/466 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs139334776; called by muse, mutect2, varscan2
- GPR171 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 63/335 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769137703, COSV56373882; called by muse, mutect2, varscan2
- GPR50 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 111/554 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.238); catalogued as rs769016022, COSV54437211; called by muse, mutect2, varscan2
- GPR78 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 180/667 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs752244272; called by muse, mutect2, varscan2
- GRB7 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 93/340 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.045); catalogued as rs767271125, COSV58448190; called by muse, mutect2, varscan2
- GRIK4 | c.2176A>G p.M726V | Missense Mutation (SNP) | VAF 69/384 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1424103775; called by muse, mutect2, varscan2
- GRM2 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 103/466 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as rs201981098, COSV99622763; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 30/144 reads (21%) | catalogued as COSV54945907; called by mutect2, varscan2
- H2AC16 | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs752544024, COSV58899086; called by muse, mutect2, varscan2
- HACD4 | c.689del p.K230Rfs*45 | Frame Shift Del (DEL) | VAF 20/128 reads (16%) | catalogued as rs768797944; called by mutect2, varscan2
- HACL1 | c.1448A>G p.N483S | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.823); catalogued as rs372054175; called by muse, mutect2, varscan2
- HADHB | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 69/324 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as rs776077327; called by muse, mutect2, varscan2
- HDAC9 | c.2839C>T p.R947C | Missense Mutation (SNP) | VAF 75/368 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs756852001; called by muse, mutect2, varscan2
- HEATR5B | c.2719G>A p.V907I | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.132); catalogued as rs183316466; called by muse, mutect2, varscan2
- HECTD4 | c.9977G>A p.R3326H | Missense Mutation (SNP) | VAF 121/455 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); catalogued as rs751778527; called by muse, mutect2, varscan2
- HELZ2 | c.4456G>A p.V1486I (on ENST00000467148 / NM_001037335.2; = p.V917I on NM_033405.3) | Missense Mutation (SNP) | VAF 139/776 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.088); catalogued as rs61739518, COSV71296959; called by muse, mutect2, varscan2
- HELZ2 | c.3629C>T p.T1210M (on ENST00000467148 / NM_001037335.2; = p.T641M on NM_033405.3) | Missense Mutation (SNP) | VAF 134/667 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs190610280; called by muse, mutect2, varscan2
- HES5 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 27/473 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.07); catalogued as COSV65830349; called by muse, mutect2
- HGS | c.1447del p.A483Rfs*2 | Frame Shift Del (DEL) | VAF 126/486 reads (26%) | catalogued as rs1555699517, COSV100230656; called by mutect2, varscan2
- HGS | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 132/570 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1203901780; called by muse, varscan2
- HHIP | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs202074993, COSV56838001; called by muse, varscan2
- HIP1R | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 118/456 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758244444; called by muse, mutect2, varscan2
- HJV | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 106/472 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.735); catalogued as rs377513689; called by mutect2, varscan2
- HMOX2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 107/484 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs148822872; called by muse, mutect2, varscan2
- HNRNPL | c.599T>C p.L200P | Missense Mutation (SNP) | VAF 89/373 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.556); catalogued as COSV55492483; called by muse, mutect2, varscan2
- HOXA7 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 308/780 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs1233857798, COSV54216847, COSV99636727; called by muse, mutect2, varscan2
- HOXC4 | c.424del p.I142Ffs*6 | Frame Shift Del (DEL) | VAF 70/351 reads (20%) | catalogued as rs754429960; called by pindel, varscan2
- HPS3 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 88/609 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV56053056; called by muse, mutect2, varscan2
- HRH2 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 96/456 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1396794379, COSV99199543; called by muse, varscan2
- HSF1 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 120/622 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs1554846182; called by muse, mutect2, varscan2
- HSPG2 | c.9112G>A p.D3038N | Missense Mutation (SNP) | VAF 131/554 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.705); catalogued as rs62642511; called by muse, mutect2, varscan2
- IGHE | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 135/522 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs1362955707; called by muse, mutect2, varscan2
- IGHV2-5 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 74/340 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs781835510; called by muse, mutect2
- IL17A | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 115/469 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs756965539, COSV60684959, COSV60685207; called by muse, mutect2, varscan2
- IL17D | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 65/773 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59231658; called by muse, mutect2
- IMPDH1 | c.964G>A p.V322M (on ENST00000470772 / NM_001142573.2; = p.V408M on NM_000883.4) | Missense Mutation (SNP) | VAF 110/623 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1451937347, COSV58316019; called by muse, mutect2, varscan2
- INCENP | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 119/497 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as rs766606953, COSV53918489; called by muse, mutect2, varscan2
- INKA2 | c.559dup p.A187Gfs*3 | Frame Shift Ins (INS) | VAF 54/370 reads (15%) | catalogued as rs751997684; called by mutect2, varscan2
- INSM2 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 174/700 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1248228841, COSV99356775; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 18/146 reads (12%) | catalogued as rs1561359523; called by mutect2, varscan2
- IQCA1 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 26/130 reads (20%) | catalogued as rs374211238, COSV54499191; called by muse, varscan2
- IQCC | c.1167del p.P390Qfs*80 | Frame Shift Del (DEL) | VAF 113/491 reads (23%) | catalogued as rs753907631; called by mutect2, pindel, varscan2
- IQGAP2 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 66/270 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.621); catalogued as rs572815114, COSV99167125; called by muse, varscan2
- IRAG1 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370614126; called by muse, mutect2, varscan2
- IRF2BPL | c.1973G>A p.S658N | Missense Mutation (SNP) | VAF 145/608 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV53146491; called by muse, mutect2, varscan2
- IRGC | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 169/624 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0.395); catalogued as rs368220155; called by muse, mutect2, varscan2
- IRS1 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 135/505 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59335026; called by muse, mutect2, varscan2
- ITGA10 | c.2605G>A p.A869T | Missense Mutation (SNP) | VAF 77/368 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.096); catalogued as rs782217182, COSV100994923; called by muse, mutect2, varscan2
- ITGA10 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 111/447 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs868939649, COSV65196420; called by muse, mutect2, varscan2
- ITGAE | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 120/520 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as rs144357698, COSV99561815; called by muse, mutect2, varscan2
- ITIH6 | c.497G>T p.R166M | Missense Mutation (SNP) | VAF 97/388 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV54495730; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 119/517 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as rs1464741179, COSV67347353; called by muse, mutect2, varscan2
- ITSN1 | c.4003C>T p.R1335C | Missense Mutation (SNP) | VAF 88/369 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201465943; called by muse, mutect2, varscan2
- KCNA3 | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 105/397 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63901187; called by muse, mutect2, varscan2
- KCNA6 | c.1372G>A p.V458I | Missense Mutation (SNP) | VAF 95/471 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54975922; called by muse, mutect2, varscan2
- KCNAB3 | c.697del p.A233Lfs*16 | Frame Shift Del (DEL) | VAF 58/378 reads (15%) | catalogued as rs745672481; called by mutect2, pindel, varscan2
- KCNH4 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 77/355 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as rs141831518, COSV52919305; called by muse, mutect2, varscan2
- KCNQ3 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs1393085163, COSV66472935; called by muse, varscan2
- KDM4B | c.2573G>A p.R858Q | Missense Mutation (SNP) | VAF 71/344 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as rs758876788, COSV50272187; called by muse, mutect2, varscan2
- KDM5B | c.2252G>A p.R751Q | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1287699615, COSV52505078; called by muse, mutect2, varscan2
- KDM6A | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 47/444 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs973676174, COSV65036843; called by muse, mutect2, varscan2
- KDM6B | c.4897G>A p.A1633T | Missense Mutation (SNP) | VAF 171/744 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.081); catalogued as rs1462085926, COSV54684235; called by muse, mutect2, varscan2
- KIAA0895 | c.844G>A p.A282T (on ENST00000297063 / NM_001100425.2; = p.A231T on NM_015314.3) | Missense Mutation (SNP) | VAF 63/422 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs754316154, COSV51709539; called by muse, mutect2, varscan2
- KIAA1522 | c.463C>T p.R155C (on ENST00000373480 / NM_001198972.2; = p.R214C on NM_020888.3) | Missense Mutation (SNP) | VAF 97/405 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs779455146; called by muse, mutect2, varscan2
- KIAA1614 | c.149del p.P50Qfs*15 | Frame Shift Del (DEL) | VAF 115/520 reads (22%) | catalogued as rs771572430; called by mutect2, pindel, varscan2
- KIF7 | c.785C>T p.T262M | Missense Mutation (SNP) | VAF 180/678 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057518271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIR2DL1 | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as COSV52414969; called by muse, mutect2, varscan2
- KLHL26 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 142/582 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs769696139, COSV56316211; called by muse, varscan2
- KLK1 | c.42dup p.T15Dfs*18 | Frame Shift Ins (INS) | VAF 62/404 reads (15%) | catalogued as rs758242614; called by mutect2, varscan2
- KMT2C | c.11557C>T p.R3853W | Missense Mutation (SNP) | VAF 94/564 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51336166, COSV51484390; called by muse, mutect2, varscan2
- KMT2C | c.5710A>G p.T1904A | Missense Mutation (SNP) | VAF 108/481 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51461956; called by muse, mutect2, varscan2
- KMT2E | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV57569070; called by muse, varscan2
- L3HYPDH | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 71/320 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371673690; called by muse, mutect2, varscan2
- L3MBTL2 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs758916893; called by muse, mutect2, varscan2
- L3MBTL3 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 80/338 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs534518041; called by muse, mutect2, varscan2
- LAMP5 | c.382A>G p.M128V | Missense Mutation (SNP) | VAF 69/394 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs770904140, COSV99855409; called by muse, mutect2, varscan2
- LCE2A | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 116/501 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100909179; called by muse, mutect2, varscan2
- LGI4 | c.869del p.G290Afs*180 | Frame Shift Del (DEL) | VAF 176/769 reads (23%) | catalogued as rs778360981; called by mutect2, pindel, varscan2
- LHFPL5 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 111/421 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs376479168; called by muse, mutect2, varscan2
- LHX9 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 102/448 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV61326814; called by muse, mutect2, varscan2
- LIG4 | c.530A>G p.Q177R | Missense Mutation (SNP) | VAF 24/275 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.038); catalogued as COSV63596967; called by muse, mutect2
- LMNTD2 | c.159G>A p.Q53= | Splice Region (SNP) | VAF 110/411 reads (27%) | catalogued as rs890678548, COSV54246214; called by muse, mutect2, varscan2
- LMTK3 | c.3650del p.P1217Lfs*99 | Frame Shift Del (DEL) | VAF 117/546 reads (21%) | catalogued as COSV54312443; called by mutect2, pindel, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 72/390 reads (18%) | catalogued as rs748712732; called by mutect2, varscan2
- LRIT1 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 82/488 reads (17%) | catalogued as COSV100928060; called by mutect2, varscan2
- LRRC37A2 | c.3912del p.K1304Nfs*11 | Frame Shift Del (DEL) | VAF 116/732 reads (16%) | catalogued as rs749596377; called by mutect2, varscan2
- LRRC3B | c.601del p.T201Lfs*17 | Frame Shift Del (DEL) | VAF 52/268 reads (19%) | catalogued as COSV67521526; called by mutect2, pindel, varscan2
- LRRC41 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 130/548 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.058); catalogued as rs781753471; called by muse, mutect2, varscan2
- LRRC53 | c.3641del p.L1214* | Frame Shift Del (DEL) | VAF 52/263 reads (20%) | catalogued as rs1450099512; called by mutect2, pindel, varscan2
- LRRC57 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 90/295 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs571068742; called by muse, varscan2
- LRRD1 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs758212934, COSV58468640; called by muse, mutect2, varscan2
- LRRN4CL | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 153/637 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54017935; called by muse, mutect2, varscan2
- LTA4H | c.894A>G p.I298M | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318138801; called by muse, mutect2, varscan2
- LZTS3 | c.1615G>A p.D539N (on ENST00000329152; = p.D493N on NM_001282533.2) | Missense Mutation (SNP) | VAF 149/808 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1191905678, COSV53907056; called by muse, mutect2, varscan2
- MAFK | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 127/644 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as rs1421880212; called by muse, mutect2, varscan2
- MAG | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1301913833; called by muse, mutect2, varscan2
- MAP3K1 | c.949T>C p.Y317H | Missense Mutation (SNP) | VAF 90/400 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101266385, COSV68129053; called by muse, mutect2, varscan2
- MAP3K11 | c.2395C>T p.R799C | Missense Mutation (SNP) | VAF 153/682 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); catalogued as rs375614171, COSV100442079; called by muse, mutect2, varscan2
- MAP3K2 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1468724553; called by muse, varscan2
- MAP3K3 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 60/281 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs761104061; called by muse, mutect2, varscan2
- MAP7D2 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 83/363 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199934348, COSV65525677; called by muse, mutect2, varscan2
- MAPK8IP1 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 153/620 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs141639373; called by muse, mutect2, varscan2
- MARF1 | c.4381G>A p.E1461K | Missense Mutation (SNP) | VAF 85/381 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs568115023, COSV60022068; called by muse, mutect2, varscan2
- MBOAT7 | c.849del p.S284Afs*39 | Frame Shift Del (DEL) | VAF 63/266 reads (24%) | catalogued as rs1382747435; called by mutect2, varscan2
- MCCC2 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 54/250 reads (22%) | catalogued as rs760881963; called by muse, varscan2
- MCOLN1 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 104/426 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs750170007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MCU | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs770146478, COSV64068211; called by muse, mutect2, varscan2
- MED12 | c.5980C>T p.R1994W | Missense Mutation (SNP) | VAF 130/495 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs1556339256, COSV61345653; ClinVar: other; called by muse, varscan2
- MED13L | c.4597C>G p.P1533A | Missense Mutation (SNP) | VAF 106/439 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56123465; called by muse, mutect2, varscan2
- MED4 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1398194412; called by muse, varscan2
- MEGF11 | c.2758G>A p.G920S | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1307925658; called by muse, mutect2, varscan2
- METAP2 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs150494953; called by muse, mutect2, varscan2
- MEX3B | c.1703T>C p.F568S | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs1456762795; called by muse, mutect2, varscan2
- MFF | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 68/259 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs369604240; called by muse, mutect2, varscan2
- MGAT5 | c.2146G>A p.A716T | Missense Mutation (SNP) | VAF 79/416 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs200390028, COSV56097533; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 122/502 reads (24%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIER2 | c.341del p.P114Rfs*6 | Frame Shift Del (DEL) | VAF 98/427 reads (23%) | catalogued as COSV53397424, COSV99316091; called by mutect2, pindel, varscan2
- MRTFA | c.1457C>A p.P486H | Missense Mutation (SNP) | VAF 20/638 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs902225829; called by muse, mutect2
- MSH3 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs368162490; called by muse, mutect2, varscan2
- MSH4 | c.2259A>C p.K753N | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs115070207; called by muse, mutect2, varscan2
- MSS51 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 57/311 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.027); catalogued as rs571329484; called by muse, mutect2, varscan2
- MTSS2 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 176/730 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1382544571; called by muse, mutect2, varscan2
- MUS81 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 87/342 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1440479669, COSV57261802; called by muse, mutect2, varscan2
- MYBPC3 | c.3452C>T p.A1151V | Missense Mutation (SNP) | VAF 99/377 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as rs779884363, COSV57029862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYCBPAP | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs761039178; called by muse, mutect2, varscan2
- MYH8 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 85/386 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs377600500; called by muse, mutect2, varscan2
- MYLK4 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV51146758; called by muse, mutect2, varscan2
- MYO10 | c.4472C>T p.A1491V | Missense Mutation (SNP) | VAF 84/484 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1367277532; called by muse, mutect2, varscan2
- MYO10 | c.3667G>A p.G1223R | Missense Mutation (SNP) | VAF 84/455 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434873123, COSV57016082, COSV57017061; called by muse, mutect2, varscan2
- MYOD1 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 123/507 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV100000334; called by muse, mutect2, varscan2
- N4BP3 | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 122/425 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV51067017; called by muse, mutect2, varscan2
- NAV2 | c.4816C>T p.R1606C (on ENST00000396087 / NM_001244963.2; = p.R1583C on NM_145117.5) | Missense Mutation (SNP) | VAF 83/412 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs202118914; called by muse, mutect2, varscan2
- NBL1 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 92/335 reads (27%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.996); catalogued as rs778071969, COSV57030298; called by muse, mutect2, varscan2
- NDRG1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 70/544 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1269503754; called by muse, mutect2, varscan2
- NEUROD6 | c.248del p.K83Rfs*35 | Frame Shift Del (DEL) | VAF 72/438 reads (16%) | catalogued as rs752284115; called by mutect2, varscan2
- NIBAN3 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 87/369 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs747029118; called by muse, mutect2, varscan2
- NID2 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 117/495 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs758004106; called by muse, mutect2, varscan2
- NKX2-4 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 118/683 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs560099970; called by muse, mutect2, varscan2
- NLRP13 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 65/301 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.012); catalogued as rs372299456; called by muse, mutect2, varscan2
- NLRP4 | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 145/511 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.249); catalogued as rs773620204; called by muse, mutect2
- NLRP6 | c.361_363del p.K121del | In Frame Del (DEL) | VAF 56/306 reads (18%) | catalogued as rs749113895; called by pindel, varscan2
- NOTCH2 | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 56/321 reads (17%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.86); catalogued as COSV56681297; called by muse, mutect2, varscan2
- NSUN7 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 120/542 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.886); catalogued as rs1384312875; called by muse, mutect2, varscan2
- NUBP1 | c.230A>G p.H77R | Missense Mutation (SNP) | VAF 97/427 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs766948315; called by muse, mutect2, varscan2
- NUDT7 | c.341T>G p.L114R | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV51745802, COSV51745955; called by muse, varscan2
- NUP98 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 121/456 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs776897983; called by muse, mutect2, varscan2
- NWD2 | c.3712G>A p.V1238M | Missense Mutation (SNP) | VAF 81/397 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs780127526; called by muse, mutect2, varscan2
- NXF1 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs892691374; called by muse, mutect2, varscan2
- NYNRIN | c.4871C>T p.P1624L | Missense Mutation (SNP) | VAF 112/446 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762806768; called by muse, mutect2, varscan2
- OBSCN | c.6634G>A p.A2212T | Missense Mutation (SNP) | VAF 94/386 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.369); catalogued as rs772794417; called by muse, varscan2
- OBSCN | c.7616G>A p.R2539Q | Missense Mutation (SNP) | VAF 116/421 reads (28%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.936); catalogued as rs377719265; called by muse, mutect2, varscan2
- OPLAH | c.3674G>A p.R1225Q | Missense Mutation (SNP) | VAF 110/549 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as rs782299905, COSV66300329; called by muse, varscan2
- OR10G8 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 74/396 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs776182491, COSV101461769, COSV70909383; called by muse, mutect2, varscan2
- OR1L4 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 61/373 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as rs150036859; called by muse, mutect2, varscan2
- OR4X2 | c.640T>G p.L214V | Missense Mutation (SNP) | VAF 88/417 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56583339, COSV56583711; called by muse, mutect2, varscan2
- OR5AR1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.145); catalogued as rs747498545; called by muse, mutect2, varscan2
- OR5M8 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 63/293 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs146940313; called by muse, mutect2, varscan2
- OTOGL | c.6501del p.K2167Nfs*40 (on ENST00000547103; = p.K2158Nfs*40 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 9/85 reads (11%) | catalogued as rs1361238129, COSV54012775; called by mutect2, pindel, varscan2
- P2RX6 | c.809G>T p.W270L | Missense Mutation (SNP) | VAF 88/372 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100298512; called by muse, mutect2, varscan2
- PARG | c.2527C>T p.R843C | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs948659889; called by muse, mutect2, varscan2
- PARS2 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 105/470 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772933788, COSV100988287; called by muse, mutect2, varscan2
- PATE1 | c.8A>G p.K3R | Missense Mutation (SNP) | VAF 71/260 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV59825423, COSV99986280; called by muse, mutect2, varscan2
- PAX7 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 114/568 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV100946958; called by muse, mutect2, varscan2
- PAXIP1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 66/340 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68184663, COSV68188102; called by muse, mutect2, varscan2
- PC | c.3193G>A p.V1065M | Missense Mutation (SNP) | VAF 147/567 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs778839142; called by muse, mutect2, varscan2
- PCDH8 | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 48/648 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.063); catalogued as rs964958368; called by muse, mutect2
- PCDH9 | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 74/388 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60559556; called by muse, mutect2, varscan2
- PCDH9 | c.77T>G p.L26R | Missense Mutation (SNP) | VAF 75/342 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.085); catalogued as COSV60532834; called by muse, mutect2, varscan2
- PCDHB1 | c.2150del p.K717Rfs*71 | Frame Shift Del (DEL) | VAF 38/221 reads (17%) | catalogued as rs782599377; called by mutect2, pindel, varscan2
- PCDHB8 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 67/606 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs148140727, COSV50755144; called by muse, mutect2, varscan2
- PCDHB9 | c.1176del p.L393* | Frame Shift Del (DEL) | VAF 63/281 reads (22%) | catalogued as rs782200278; called by mutect2, pindel, varscan2
- PCDHGA1 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 80/356 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.022); catalogued as rs775979127; called by muse, mutect2, varscan2
- PCDHGB7 | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 98/477 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.106); catalogued as COSV104390143; called by muse, mutect2, varscan2
- PDHX | c.401_403del p.E134del | In Frame Del (DEL) | VAF 50/252 reads (20%) | catalogued as rs1565159802; called by pindel, varscan2
- PDPK1 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 86/480 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1305262606; called by muse, mutect2, varscan2
- PDXK | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 86/366 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs200647993, COSV52366093; called by muse, varscan2
- PGBD4 | c.1751del p.N584Ifs*21 | Frame Shift Del (DEL) | VAF 58/231 reads (25%) | catalogued as rs770560794; called by mutect2, varscan2
- PHACTR3 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 91/467 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs765373916; called by muse, mutect2, varscan2
- PHKA2 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 91/438 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.964); catalogued as rs768524028, COSV101176503; called by muse, mutect2, varscan2
- PICALM | c.1822A>G p.M608V | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as rs760045537; called by muse, mutect2, varscan2
- PKD1 | c.6605C>T p.A2202V | Missense Mutation (SNP) | VAF 191/742 reads (26%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.453); catalogued as rs764264106; called by muse, mutect2, varscan2
- PKD1L2 | c.300G>T p.E100D | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs201146112; called by muse, mutect2, varscan2
- PKHD1L1 | c.5054C>T p.A1685V | Missense Mutation (SNP) | VAF 65/410 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as rs141467551; called by muse, mutect2, varscan2
- PKN1 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 155/631 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs778487912; called by muse, mutect2, varscan2
- PKN1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 77/409 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs770373043, COSV54395737; called by muse, mutect2, varscan2
- PLA2G4D | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 157/583 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1170265758; called by muse, mutect2, varscan2
- PLK1 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 81/338 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as rs778360538, COSV99890823; called by muse, mutect2, varscan2
- PLSCR5 | c.636G>T p.K212N | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV71649216; called by muse, mutect2, varscan2
- PNPO | c.236A>G p.N79S | Missense Mutation (SNP) | VAF 62/277 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs755839067; called by muse, mutect2
- POPDC2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 67/321 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs564285845; called by muse, mutect2, varscan2
- POTEJ | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 100/620 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.111); catalogued as rs1168552300; called by muse, varscan2
- PPM1F | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 120/496 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781432214; called by muse, mutect2, varscan2
- PPP3R2 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 95/544 reads (17%) | catalogued as COSV100701960; called by muse, mutect2, varscan2
- PQBP1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 96/468 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs1249414837; called by muse, mutect2, varscan2
- PRCC | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 58/342 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54857636; called by muse, mutect2, varscan2
- PREX2 | c.182T>G p.V61G | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.122); catalogued as COSV55749368; called by muse, mutect2, varscan2
- PRICKLE1 | c.2462del p.K821Rfs*26 | Frame Shift Del (DEL) | VAF 70/315 reads (22%) | catalogued as COSV58207444; called by mutect2, pindel, varscan2
- PRICKLE2 | c.1873C>T p.R625* (on ENST00000295902; = p.R569* on NM_198859.4) | Nonsense Mutation (SNP) | VAF 73/327 reads (22%) | catalogued as COSV55765923, COSV55772339, COSV99898213; called by muse, mutect2, varscan2
- PRKCD | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 112/416 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190070838, COSV57847601; called by mutect2, varscan2
- PRMT8 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 84/375 reads (22%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as rs750637534, COSV54212495; called by muse, mutect2, varscan2
- PROCA1 | c.294C>A p.H98Q (on ENST00000439862 / NM_001366301.1; = p.H70Q on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/328 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs759599083; called by muse, mutect2, varscan2
- PROSER2 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 186/723 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1329328983, COSV99508832; called by muse, mutect2, varscan2
- PRR22 | c.1115del p.P372Lfs*? | Frame Shift Del (DEL) | VAF 144/584 reads (25%) | catalogued as rs761300125; called by mutect2, pindel, varscan2
- PTPRB | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 85/352 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as rs373051218; called by muse, mutect2, varscan2
- PTPRT | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 48/336 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1444440253, COSV100628643; called by muse, varscan2
- PXDC1 | c.109_111del p.E37del | In Frame Del (DEL) | VAF 131/552 reads (24%) | catalogued as rs1383567847; called by pindel, varscan2
- QRICH2 | c.4763T>C p.M1588T | Missense Mutation (SNP) | VAF 136/414 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs560754192; called by muse, mutect2, varscan2
- RAD51AP2 | c.1595G>A p.C532Y | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1355339488; called by muse, mutect2
- RADIL | c.3173C>T p.A1058V | Missense Mutation (SNP) | VAF 152/401 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1302005389, COSV68198861; called by muse, mutect2, varscan2
- RALGAPA2 | c.2798G>A p.R933Q | Missense Mutation (SNP) | VAF 94/488 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs201350348; called by muse, mutect2, varscan2
- RAPGEF1 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 100/480 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs1368828475; called by muse, mutect2, varscan2
- RAPGEF2 | c.4429C>T p.R1477C | Missense Mutation (SNP) | VAF 79/336 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.394); catalogued as rs374988798; called by muse, mutect2, varscan2
- RASA1 | c.2513del p.N838Mfs*4 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs1561325048; called by mutect2, pindel, varscan2
- RASA3 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs754833145, COSV61874889; called by muse, mutect2, varscan2
- RASL12 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 78/360 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1235058907; called by muse, mutect2, varscan2
- RBMXL2 | c.964G>A p.G322S | Missense Mutation (SNP) | VAF 107/458 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.079); catalogued as rs1460115501, COSV100182137, COSV100182212; called by muse, mutect2, varscan2
- RBMXL3 | c.3139G>A p.V1047M | Missense Mutation (SNP) | VAF 96/436 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as rs1556561529; called by muse, mutect2, varscan2
- REV1 | c.1200_1202del p.V401del | In Frame Del (DEL) | VAF 26/128 reads (20%) | catalogued as rs777315177; called by pindel, varscan2
- RGS7BP | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); catalogued as rs1265717700, COSV61836881; called by muse, mutect2, varscan2
- RGSL1 | c.2717C>A p.A906E | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as rs937262384; called by muse, mutect2, varscan2
- RIMS1 | c.2873G>A p.R958H | Missense Mutation (SNP) | VAF 51/313 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373238402, COSV99327156; called by muse, mutect2, varscan2
- RRP36 | c.43_66del p.G15_A22del | In Frame Del (DEL) | VAF 73/418 reads (17%) | catalogued as rs746688436; called by mutect2, varscan2
- RTCA | c.38T>C p.M13T | Missense Mutation (SNP) | VAF 112/512 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs755406238, COSV53120737; called by muse, mutect2, varscan2
- RTEL1 | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 128/696 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as rs941024707; called by muse, varscan2
- RXRA | c.332del p.L111Rfs*57 | Frame Shift Del (DEL) | VAF 123/659 reads (19%) | catalogued as COSV62683760; called by mutect2, pindel, varscan2
- SAA2 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 104/450 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs750654169, COSV99879352; called by muse, mutect2, varscan2
- SAFB2 | c.2471del p.G824Afs*8 | Frame Shift Del (DEL) | VAF 96/493 reads (19%) | catalogued as rs759920279; called by mutect2, pindel, varscan2
- SALL3 | c.906del p.G303Afs*92 | Frame Shift Del (DEL) | VAF 43/137 reads (31%) | catalogued as rs1424702195; called by mutect2, pindel, varscan2
- SAMD14 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 90/379 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs761980026, COSV50303246; called by muse, mutect2, varscan2
- SCN7A | c.4310A>G p.D1437G | Missense Mutation (SNP) | VAF 71/293 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1389213565; called by muse, mutect2, varscan2
- SDC3 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 47/289 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763990227; called by muse, mutect2, varscan2
- SDK2 | c.1447del p.V483Sfs*8 | Frame Shift Del (DEL) | VAF 88/386 reads (23%) | catalogued as COSV66183488; called by mutect2, varscan2
- SEL1L | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 41/197 reads (21%) | catalogued as rs777962520, COSV100377853; called by muse, varscan2
- SEMA4F | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 71/324 reads (22%) | catalogued as rs749486094, COSV60284007; called by muse, mutect2, varscan2
- SEMA6A | c.2884G>A p.A962T | Missense Mutation (SNP) | VAF 32/573 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.049); catalogued as rs771191183; called by muse, mutect2
- SFRP4 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 160/499 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs771031038, COSV101460863, COSV71412297; called by muse, mutect2, varscan2
- SFRP5 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 125/703 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.166); catalogued as rs772368228, COSV56604843; called by muse, mutect2, varscan2
- SFXN5 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as rs775582497; called by muse, varscan2
- SHROOM3 | c.2714G>A p.R905Q | Missense Mutation (SNP) | VAF 164/654 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1053959892; called by muse, mutect2, varscan2
- SHROOM4 | c.2372G>A p.G791D | Missense Mutation (SNP) | VAF 86/412 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs149352975; called by muse, mutect2, varscan2
- SHROOM4 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 83/362 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1455083919; called by muse, mutect2, varscan2
- SKIV2L | c.262T>C p.W88R | Missense Mutation (SNP) | VAF 113/475 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.042); catalogued as rs1438641225; called by muse, mutect2, varscan2
- SLC12A1 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100372478; called by muse, mutect2, varscan2
- SLC12A3 | c.2099T>C p.L700P | Missense Mutation (SNP) | VAF 106/393 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM160524; called by muse, mutect2, varscan2
- SLC12A6 | c.322G>A p.G108R (on ENST00000354181 / NM_001365088.1; = p.G57R on NM_005135.2) | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs746589334; called by muse, mutect2, varscan2
- SLC16A6 | c.294dup p.L99Afs*34 | Frame Shift Ins (INS) | VAF 74/353 reads (21%) | catalogued as rs782184620; called by mutect2, varscan2
- SLC22A24 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs755232708, COSV70300508; called by muse, mutect2, varscan2
- SLC26A8 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 85/389 reads (22%) | catalogued as rs1346725120, COSV62885355; called by muse, mutect2, varscan2
- SLC27A3 | c.826T>C p.F276L (on ENST00000271857; = p.F148L on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/948 reads (4%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs1041415643; called by muse, mutect2
- SLC38A3 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs780089718; called by muse, mutect2, varscan2
- SLC45A2 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 61/369 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs372465070, HM0682, COSV56873036; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC5A1 | c.728T>C p.I243T | Missense Mutation (SNP) | VAF 83/364 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs755240209; called by muse, varscan2
- SLC9B2 | c.173del p.K58Sfs*15 | Frame Shift Del (DEL) | VAF 79/316 reads (25%) | catalogued as COSV100294119; called by mutect2, pindel, varscan2
- SMARCA4 | c.4090G>A p.E1364K | Missense Mutation (SNP) | VAF 127/454 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV100759140, COSV60796160; called by muse, mutect2, varscan2
- SMARCC2 | c.2666C>A p.A889D | Missense Mutation (SNP) | VAF 73/361 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99911314; called by muse, mutect2, varscan2
- SNX5 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 56/370 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs746639789, COSV66698609; called by muse, mutect2, varscan2
- SOX13 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 102/431 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs770201579, COSV99690051; called by muse, mutect2, varscan2
- SP140L | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 79/294 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV54745148; called by muse, mutect2, varscan2
- SPATC1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 136/625 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs572527417, COSV66299396; called by muse, mutect2, varscan2
- SPEG | c.2744G>A p.R915H | Missense Mutation (SNP) | VAF 126/535 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.061); catalogued as rs778684137, COSV56665740; called by muse, mutect2, varscan2
- SPOCD1 | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 121/555 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.268); catalogued as COSV57096234; called by muse, mutect2, varscan2
- SQOR | c.88del p.L30Ffs*33 | Frame Shift Del (DEL) | VAF 111/538 reads (21%) | catalogued as rs1473436960; called by mutect2, pindel, varscan2
- SREBF2 | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 102/417 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1182528443; called by muse, mutect2, varscan2
- SRP19 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs961917242; called by muse, mutect2, varscan2
- SRP72 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 73/276 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as rs143909076; called by muse, mutect2, varscan2
- STAT1 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 96/371 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as rs369060692; called by muse, mutect2, varscan2
- STAU1 | c.724G>A p.A242T (on ENST00000371856 / NM_001319135.1; = p.A161T on NM_004602.3) | Missense Mutation (SNP) | VAF 16/558 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61460360; called by muse, mutect2
- STIL | c.2385T>C p.G795= | Splice Region (SNP) | VAF 57/224 reads (25%) | catalogued as rs1168359252; called by muse, mutect2, varscan2
- STK11IP | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 79/292 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs145503364; called by muse, mutect2, varscan2
- STRN4 | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 162/673 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1022211963; called by muse, mutect2, varscan2
- SULF2 | c.676dup p.H226Pfs*4 | Frame Shift Ins (INS) | VAF 119/671 reads (18%) | catalogued as rs774011241; called by mutect2, pindel, varscan2
- SV2A | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 90/399 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs782452680, COSV100975151; called by muse, mutect2, varscan2
- SVEP1 | c.7535C>T p.T2512M | Missense Mutation (SNP) | VAF 113/498 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs200375910; called by muse, mutect2, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 30/199 reads (15%) | catalogued as rs753462162; called by mutect2, varscan2*
- SYNJ2 | c.2462A>G p.N821S | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1386308726; called by muse, mutect2, varscan2
- TACC3 | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 69/353 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1419297079; called by muse, mutect2, varscan2
- TACR3 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 159/655 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV59202383; called by muse, mutect2, varscan2
- TAF11L2 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 105/519 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.929); catalogued as rs570980460; called by muse, mutect2, varscan2
- TAF7L | c.1337dup p.N446Kfs*2 | Frame Shift Ins (INS) | VAF 28/143 reads (20%) | catalogued as rs780573926; called by mutect2, varscan2
- TARBP2 | c.432dup p.M145Hfs*13 (on ENST00000266987 / NM_134323.2; = p.M124Hfs*13 on NM_004178.4) | Frame Shift Ins (INS) | VAF 102/424 reads (24%) | catalogued as rs750181498; called by mutect2, varscan2
- TATDN2 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs774447497, COSV55053006; called by muse, mutect2, varscan2
- TBCE | c.1025del p.N342Tfs*19 (on ENST00000366601; = p.N405Tfs*19 on NM_003193.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 116/476 reads (24%) | catalogued as rs748417931; called by mutect2, varscan2
- TBL2 | c.1297A>T p.T433S | Missense Mutation (SNP) | VAF 115/731 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV59786400; called by muse, mutect2, varscan2
- TBX10 | c.343A>G p.M115V | Missense Mutation (SNP) | VAF 94/445 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs1349522929; called by muse, mutect2, varscan2
- TENM2 | c.4105A>G p.M1369V (on ENST00000518659 / NM_001122679.2; = p.M1130V on NM_001080428.3) | Missense Mutation (SNP) | VAF 34/253 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1217279498, COSV69138610; called by muse, mutect2, varscan2
- TG | c.2816C>T p.T939M | Missense Mutation (SNP) | VAF 196/516 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs1158331818, COSV55093883; called by muse, mutect2, varscan2
- TGFBI | c.1502del p.P501Qfs*9 | Frame Shift Del (DEL) | VAF 74/418 reads (18%) | catalogued as rs771515402; called by pindel, varscan2
- THSD1 | c.221C>T p.T74I | Missense Mutation (SNP) | VAF 93/475 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs758702070; called by muse, mutect2, varscan2
- TIE1 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 88/376 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs753706088, COSV65249967; called by muse, mutect2, varscan2
- TLR9 | c.2206G>A p.A736T | Missense Mutation (SNP) | VAF 114/516 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.558); catalogued as rs895456647, COSV62346165; called by muse, mutect2, varscan2
- TMEM132A | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 142/543 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as rs929716792, COSV50000787; called by muse, mutect2, varscan2
- TMEM132E | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 113/512 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.99); catalogued as COSV58698857; called by muse, mutect2
- TMEM201 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 99/456 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs371304568; called by muse, mutect2, varscan2
- TMEM52B | c.280G>A p.D94N (on ENST00000381923 / NM_001079815.1; = p.D74N on NM_153022.4) | Missense Mutation (SNP) | VAF 54/310 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781587745; called by muse, mutect2, varscan2
- TNC | c.4505C>T p.T1502I | Missense Mutation (SNP) | VAF 75/422 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.799); catalogued as rs1395205574, COSV60785975; called by muse, mutect2, varscan2
- TNRC6B | c.5387del p.P1796Qfs*59 (on ENST00000454349 / NM_001162501.2; = p.P1686Qfs*59 on NM_015088.3) | Frame Shift Del (DEL) | VAF 118/538 reads (22%) | catalogued as COSV100110716; called by mutect2, pindel, varscan2
- TNXB | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 111/480 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs139154852, CM1510098; called by muse, mutect2, varscan2
- TOR1AIP2 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 74/318 reads (23%) | catalogued as rs1188835981, COSV62626832; called by muse, mutect2, varscan2
- TOR1B | c.719T>C p.L240P | Missense Mutation (SNP) | VAF 88/414 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as rs1460986896; called by muse, mutect2, varscan2
- TP73 | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 154/612 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs141383785; called by muse, mutect2
- TPO | c.611del p.P204Rfs*5 | Frame Shift Del (DEL) | VAF 86/349 reads (25%) | catalogued as COSV100219300; called by mutect2, pindel, varscan2
- TRIO | c.6895A>G p.S2299G | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.153); catalogued as rs745851077, COSV100702682; called by mutect2, varscan2
- TRIP12 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs199893260, COSV52264214, COSV99389245; called by muse, mutect2, varscan2
- TRRAP | c.5873C>T p.P1958L (on ENST00000359863 / NM_001244580.1; = p.P1940L on NM_003496.3) | Missense Mutation (SNP) | VAF 83/484 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.201); catalogued as rs1353927836, COSV100722703, COSV62842516; called by muse, mutect2, varscan2
- TSPYL2 | c.378dup p.S127Efs*24 | Frame Shift Ins (INS) | VAF 138/646 reads (21%) | catalogued as rs782157673; called by mutect2, varscan2
- TSSK2 | c.825del p.K276Sfs*30 | Frame Shift Del (DEL) | VAF 127/466 reads (27%) | catalogued as rs764514103; called by mutect2, pindel, varscan2
- TTC28 | c.4091C>T p.T1364M | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs755114255; called by muse, mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 44/198 reads (22%) | catalogued as rs756650873; called by mutect2, varscan2
- TUBA3C | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 112/556 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.037); catalogued as rs373201894, COSV67139696, COSV67139935; called by muse, mutect2, varscan2
- TYK2 | c.2296G>A p.A766T | Missense Mutation (SNP) | VAF 100/436 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs752837292; called by muse, mutect2, varscan2
- UBA7 | c.2756T>C p.V919A | Missense Mutation (SNP) | VAF 111/451 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs1312194057; called by muse, mutect2, varscan2
- UBE2M | c.70A>G p.S24G | Missense Mutation (SNP) | VAF 104/435 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1446903177; called by muse, mutect2, varscan2
- UNC5B | c.303C>T p.T101= | Splice Region (SNP) | VAF 47/243 reads (19%) | catalogued as rs146776724; called by muse, mutect2, varscan2
- UNC79 | c.1336G>A p.V446M (on ENST00000393151 / NM_001346218.2; = p.V269M on NM_020818.5) | Missense Mutation (SNP) | VAF 106/454 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1240436849, COSV56397569; called by muse, mutect2, varscan2
- UPP1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 70/439 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1248574098; called by muse, mutect2, varscan2
- USP29 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 69/294 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.566); catalogued as rs535698771, COSV54141233; called by muse, mutect2, varscan2
- USP34 | c.10550A>G p.H3517R | Missense Mutation (SNP) | VAF 71/349 reads (20%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); catalogued as rs201379721; called by muse, mutect2, varscan2
- UTF1 | c.749del p.P250Rfs*26 | Frame Shift Del (DEL) | VAF 100/480 reads (21%) | catalogued as rs898770563; called by mutect2, pindel, varscan2
- UVRAG | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 78/315 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.816); catalogued as rs773553252, COSV62103696; called by muse, mutect2, varscan2
- UXT | c.43del p.E15Rfs*38 | Frame Shift Del (DEL) | VAF 110/522 reads (21%) | catalogued as COSV100243846, COSV100243923; called by mutect2, pindel, varscan2
- VASH2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 73/300 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs771662401, COSV55119439, COSV55119632; called by muse, mutect2, varscan2
- VPS25 | c.119_121del p.F40del | In Frame Del (DEL) | VAF 84/376 reads (22%) | catalogued as rs1409393818; called by mutect2, pindel, varscan2
- VPS33A | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.436); catalogued as rs142468494; called by muse, mutect2, varscan2
- VPS37D | c.748del p.H250Tfs*75 | Frame Shift Del (DEL) | VAF 60/266 reads (23%) | catalogued as rs1563540888; called by mutect2, varscan2
- WDR4 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs200755631, COSV100375414; called by muse, mutect2, varscan2
- WDR70 | c.1953dup p.R652Tfs*2 | Frame Shift Ins (INS) | VAF 31/214 reads (14%) | catalogued as rs775718229; called by mutect2, pindel, varscan2
- WWP1 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1043774516, COSV55364357; called by muse, mutect2, varscan2
- ZBTB20 | c.833G>A p.R278H (on ENST00000474710 / NM_001164342.2; = p.R205H on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/440 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs377711773; called by muse, mutect2, varscan2
- ZBTB33 | c.1527G>T p.L509F | Missense Mutation (SNP) | VAF 69/329 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV58533749; called by muse, mutect2, varscan2
- ZFHX4 | c.1230dup p.L411Afs*3 | Frame Shift Ins (INS) | VAF 70/451 reads (16%) | catalogued as rs761578656; called by mutect2, varscan2
- ZFP37 | c.482del p.N161Ifs*24 | Frame Shift Del (DEL) | VAF 48/212 reads (23%) | catalogued as rs563751025; called by mutect2, varscan2
- ZFPM1 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs764706785; called by muse, mutect2
- ZFYVE9 | c.2933T>C p.I978T | Missense Mutation (SNP) | VAF 88/355 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs780837585; called by muse, mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 80/316 reads (25%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF217 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 107/559 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs372777442; called by muse, mutect2, varscan2
- ZNF239 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 110/611 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1194561727, COSV60017979; called by muse, mutect2, varscan2
- ZNF257 | c.1349A>C p.K450T | Missense Mutation (SNP) | VAF 59/241 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV71309813, COSV71313366; called by muse, mutect2, varscan2
- ZNF28 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 87/371 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as rs574742869; called by muse, mutect2, varscan2
- ZNF283 | c.370del p.I124Yfs*10 | Frame Shift Del (DEL) | VAF 14/100 reads (14%) | catalogued as rs779324028; called by pindel, varscan2
- ZNF317 | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 84/400 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs376791164; called by muse, mutect2, varscan2
- ZNF404 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.685); catalogued as rs769536602; called by muse, mutect2, varscan2
- ZNF407 | c.5830G>A p.V1944M | Missense Mutation (SNP) | VAF 114/527 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs1027928506; called by muse, mutect2, varscan2
- ZNF43 | c.752del p.N251Ifs*28 | Frame Shift Del (DEL) | VAF 37/160 reads (23%) | catalogued as rs753886536; called by mutect2, varscan2
- ZNF461 | c.526A>G p.S176G | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs374942056; called by muse, mutect2, varscan2
- ZNF497 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 145/581 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs775744493; called by muse, mutect2, varscan2
- ZNF512B | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 97/563 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs199612485, COSV53877654; called by muse, mutect2, varscan2
- ZNF512B | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 79/379 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1416504611; called by muse, mutect2, varscan2
- ZNF521 | c.1925A>C p.K642T | Missense Mutation (SNP) | VAF 78/366 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as COSV100831300, COSV64123106; called by muse, mutect2, varscan2
- ZNF536 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 130/540 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62819615; called by muse, mutect2, varscan2
- ZNF567 | c.756del p.K252Nfs*17 (on ENST00000536254 / NM_001322913.1; = p.K221Nfs*17 on NM_152603.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 39/162 reads (24%) | catalogued as rs762873548; called by mutect2, varscan2
- ZNF658 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 33/507 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs1316361917; called by muse, mutect2
- ZNF681 | c.504del p.K168Nfs*18 | Frame Shift Del (DEL) | VAF 25/126 reads (20%) | catalogued as rs745843775; called by mutect2, pindel, varscan2
- ZNF814 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 85/404 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs768180681, COSV71381925; called by muse, mutect2, varscan2
- ZNF865 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 154/562 reads (27%) | SIFT tolerated, low confidence (0.07); catalogued as rs771117617; called by muse, varscan2
- ZNF880 | c.1611del p.K537Nfs*60 | Frame Shift Del (DEL) | VAF 54/248 reads (22%) | catalogued as rs759348115; called by mutect2, varscan2
- ZSCAN20 | c.1549T>C p.Y517H | Missense Mutation (SNP) | VAF 103/446 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100792676; called by muse, mutect2, varscan2
- ABCA10 | c.93del p.K31Nfs*18 | Frame Shift Del (DEL) | VAF 25/181 reads (14%) | called by mutect2, pindel, varscan2
- ABCA6 | c.4133A>G p.Y1378C | Missense Mutation (SNP) | VAF 93/410 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ABCA9 | c.3589T>C p.S1197P | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, varscan2
- ABHD17C | c.941A>G p.Y314C | Missense Mutation (SNP) | VAF 78/292 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- AC004922.1 | c.1163C>T p.T388I | Missense Mutation (SNP) | VAF 73/372 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AC008397.2 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 82/245 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACACB | c.4333T>C p.F1445L | Missense Mutation (SNP) | VAF 81/320 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACAP3 | c.1732C>T p.R578* | Nonsense Mutation (SNP) | VAF 100/419 reads (24%) | called by muse, mutect2, varscan2
- ACSL4 | c.2030C>A p.P677Q (on ENST00000340800 / NM_022977.2; = p.P636Q on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/319 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ACSL4 | c.2029C>T p.P677S (on ENST00000340800 / NM_022977.2; = p.P636S on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- ACVR1B | c.950A>G p.H317R | Missense Mutation (SNP) | VAF 81/334 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM12 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 117/511 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS15 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 165/679 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS19 | c.2968G>T p.E990* | Nonsense Mutation (SNP) | VAF 33/265 reads (12%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.2969A>T p.E990V | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ADAMTS2 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 154/683 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY5 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 127/532 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- ADGB | c.271T>G p.L91V | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- ADGRA2 | c.1868del p.P623Rfs*69 | Frame Shift Del (DEL) | VAF 130/531 reads (24%) | called by mutect2, pindel, varscan2
- ADGRE5 | c.637T>C p.C213R (on ENST00000242786 / NM_078481.4; = p.C120R on NM_001784.5) | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRF4 | c.929T>C p.V310A | Missense Mutation (SNP) | VAF 80/297 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRL2 | c.2026A>C p.S676R (on ENST00000370717 / NM_001366005.1; = p.S663R on NM_012302.4) | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- ADGRL4 | c.1645G>C p.A549P | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRV1 | c.9938A>G p.E3313G | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2
- ADK | c.312del p.F104Lfs*6 (on ENST00000286621; = p.F87Lfs*6 on NM_001123.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 57/341 reads (17%) | called by mutect2, pindel, varscan2
- AFF1 | c.3080+3_3080+6del p.X1027_splice | Splice Site (DEL) | VAF 49/218 reads (22%) | called by pindel, varscan2
- AGL | c.4434A>G p.I1478M | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- AGMO | c.1097T>G p.L366R | Missense Mutation (SNP) | VAF 78/358 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- AGRN | c.3940G>A p.A1314T | Missense Mutation (SNP) | VAF 94/464 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHNAK | c.7128G>A p.M2376I | Missense Mutation (SNP) | VAF 147/555 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- AHNAK | c.6815T>C p.V2272A | Missense Mutation (SNP) | VAF 146/584 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AKR1C2 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 60/320 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.02); called by muse, varscan2
- ALDH1L1 | c.124del p.L42Wfs*53 | Frame Shift Del (DEL) | VAF 57/332 reads (17%) | called by mutect2, pindel, varscan2
- AMER1 | c.519del p.F173Lfs*36 | Frame Shift Del (DEL) | VAF 99/472 reads (21%) | called by mutect2, pindel, varscan2
- ANKEF1 | c.59_60del p.V20Afs*18 | Frame Shift Del (DEL) | VAF 52/336 reads (15%) | called by pindel, varscan2
- ANKEF1 | c.2243A>T p.H748L | Missense Mutation (SNP) | VAF 80/431 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, varscan2
- ANKRD18A | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 116/634 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ANKRD2 | c.413del p.P138Qfs*16 | Frame Shift Del (DEL) | VAF 112/594 reads (19%) | called by mutect2, pindel, varscan2
- ANKRD50 | c.3343A>G p.T1115A | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANKRD7 | c.218A>C p.D73A | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ANKUB1 | c.895T>C p.S299P | Missense Mutation (SNP) | VAF 11/291 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANTXR1 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 57/281 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANXA11 | c.1323_1325del p.N441del | In Frame Del (DEL) | VAF 50/312 reads (16%) | called by pindel, varscan2
- AP3M2 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 83/349 reads (24%) | called by muse, mutect2, varscan2
- AP5B1 | c.2454_2456del p.F818_V819delinsL | In Frame Del (DEL) | VAF 116/531 reads (22%) | called by mutect2, pindel, varscan2
- AP5Z1 | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 126/642 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- APBB1 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 146/553 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARGLU1 | c.353A>C p.Q118P | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ARHGAP21 | c.889A>G p.R297G | Missense Mutation (SNP) | VAF 84/438 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF10L | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 86/367 reads (23%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- ARHGEF17 | c.1850del p.P617Lfs*10 | Frame Shift Del (DEL) | VAF 95/470 reads (20%) | called by mutect2, pindel, varscan2
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 95/422 reads (23%) | called by mutect2, pindel, varscan2
- ARID5B | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 129/613 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARIH2 | c.1276T>C p.Y426H | Missense Mutation (SNP) | VAF 56/281 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARMCX5 | c.984T>A p.H328Q | Missense Mutation (SNP) | VAF 77/329 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ASB4 | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 100/553 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, varscan2
- ASMTL | c.1534A>G p.R512G | Missense Mutation (SNP) | VAF 17/416 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2
- ASTN1 | c.2455A>G p.K819E | Missense Mutation (SNP) | VAF 68/292 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ATAD2 | c.503A>G p.N168S | Missense Mutation (SNP) | VAF 43/272 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- ATG2A | c.3317del p.P1106Rfs*87 | Frame Shift Del (DEL) | VAF 60/314 reads (19%) | called by mutect2, varscan2
- ATP1A4 | c.2353A>G p.T785A | Missense Mutation (SNP) | VAF 14/442 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATP1B3 | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ATP2B1 | c.1601_1602del p.E534Gfs*9 | Frame Shift Del (DEL) | VAF 30/162 reads (19%) | called by pindel, varscan2
- ATP9A | c.545del p.N182Tfs*71 | Frame Shift Del (DEL) | VAF 51/363 reads (14%) | called by mutect2, pindel, varscan2
- ATXN7L3 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 123/539 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AXL | c.764T>C p.L255P | Missense Mutation (SNP) | VAF 95/378 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- B3GAT1 | c.448del p.R150Afs*83 | Frame Shift Del (DEL) | VAF 157/765 reads (21%) | called by mutect2, pindel, varscan2
- B4GALNT4 | c.2723G>A p.S908N | Missense Mutation (SNP) | VAF 94/375 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BBS2 | c.70T>C p.Y24H | Missense Mutation (SNP) | VAF 112/453 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- BHLHA9 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 126/449 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMP6 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 121/403 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BSN | c.6736A>G p.M2246V | Missense Mutation (SNP) | VAF 130/488 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BUD13 | c.1685T>C p.V562A | Missense Mutation (SNP) | VAF 62/282 reads (22%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- C11orf96 | c.1213C>T p.R405C (on ENST00000339446; = p.R92C on NM_001145033.2) | Missense Mutation (SNP) | VAF 102/427 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- C1QBP | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 63/257 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- C1QTNF12 | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 99/426 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C1orf74 | c.167_168del p.Y56* | Frame Shift Del (DEL) | VAF 127/539 reads (24%) | called by mutect2, pindel, varscan2
- C3 | c.1904A>G p.Y635C | Missense Mutation (SNP) | VAF 91/368 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- C4orf50 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 130/553 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C4orf54 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 123/478 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C5orf22 | c.326_327del p.E109Gfs*28 | Frame Shift Del (DEL) | VAF 49/318 reads (15%) | called by pindel, varscan2
- C8orf48 | c.258del p.K86Nfs*34 | Frame Shift Del (DEL) | VAF 63/282 reads (22%) | called by mutect2, pindel, varscan2
- CABLES2 | c.101A>C p.Q34P | Missense Mutation (SNP) | VAF 13/225 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- CACNA1D | c.4210A>G p.T1404A (on ENST00000350061 / NM_001128840.3; = p.T1424A on NM_000720.4) | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CALD1 | c.104A>C p.E35A | Missense Mutation (SNP) | VAF 93/469 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAMK1D | c.164del p.P55Lfs*5 | Frame Shift Del (DEL) | VAF 64/432 reads (15%) | called by mutect2, pindel, varscan2
- CAMTA2 | c.1397del p.P466Lfs*17 | Frame Shift Del (DEL) | VAF 73/336 reads (22%) | called by mutect2, pindel, varscan2
- CAPN1 | c.1247G>A p.G416D | Missense Mutation (SNP) | VAF 165/580 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CAPZB | c.235T>C p.Y79H | Missense Mutation (SNP) | VAF 90/340 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CARD10 | c.2428del p.A810Rfs*55 | Frame Shift Del (DEL) | VAF 118/591 reads (20%) | called by mutect2, pindel, varscan2
- CARMIL2 | c.920G>T p.R307M | Missense Mutation (SNP) | VAF 77/378 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- CASP2 | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 134/559 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- CASP8 | c.1419dup p.L474Tfs*6 (on ENST00000432109 / NM_033355.3; = p.L491Tfs*6 on NM_001228.4) | Frame Shift Ins (INS) | VAF 40/198 reads (20%) | called by mutect2, varscan2
- CBLC | c.161T>C p.L54P | Missense Mutation (SNP) | VAF 174/696 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCDC168 | c.17202A>G p.I5734M | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- CCDC169 | c.605del p.K202Rfs*35 | Frame Shift Del (DEL) | VAF 48/240 reads (20%) | called by mutect2, pindel, varscan2
- CCDC185 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 128/544 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCDC47 | c.377C>A p.P126H | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CCDC68 | c.552del p.K184Nfs*23 | Frame Shift Del (DEL) | VAF 25/167 reads (15%) | called by mutect2, pindel, varscan2
- CCDC71L | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 130/671 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CD14 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 128/519 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CD58 | c.156del p.E53Rfs*31 | Frame Shift Del (DEL) | VAF 39/208 reads (19%) | called by mutect2, pindel, varscan2
- CD93 | c.943del p.A315Pfs*273 | Frame Shift Del (DEL) | VAF 94/662 reads (14%) | called by pindel, varscan2
- CDCA7 | c.383T>C p.M128T (on ENST00000347703 / NM_145810.3; = p.M207T on NM_031942.5) | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, varscan2
- CDH23 | c.8267C>T p.A2756V | Missense Mutation (SNP) | VAF 102/558 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CDK12 | c.3779T>G p.L1260R | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CDKL4 | c.701del p.F234Sfs*27 | Frame Shift Del (DEL) | VAF 61/264 reads (23%) | called by mutect2, pindel, varscan2
- CELF4 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 108/524 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CELSR1 | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 74/501 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP112 | c.2664del p.K888Nfs*13 (on ENST00000392769 / NM_001353127.1; = p.K144Nfs*13 on NM_001037325.3) | Frame Shift Del (DEL) | VAF 39/212 reads (18%) | called by mutect2, pindel, varscan2
- CETP | c.1013T>C p.V338A | Missense Mutation (SNP) | VAF 21/410 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.526); called by muse, mutect2
- CFAP157 | c.1219A>G p.M407V | Missense Mutation (SNP) | VAF 93/541 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CFAP43 | c.102del p.F34Lfs*15 | Frame Shift Del (DEL) | VAF 41/262 reads (16%) | called by mutect2, pindel, varscan2
- CFAP46 | c.4004A>G p.Q1335R | Missense Mutation (SNP) | VAF 23/410 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2
- CHD5 | c.3205C>T p.R1069W | Missense Mutation (SNP) | VAF 72/358 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHERP | c.2144A>G p.E715G | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CHKB | c.964_965insTT p.K322Ifs*20 | Frame Shift Ins (INS) | VAF 64/296 reads (22%) | called by mutect2, pindel, varscan2
- CHL1 | c.1550T>G p.L517R (on ENST00000397491 / NM_001253387.1; = p.L533R on NM_006614.4) | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CHST13 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 131/571 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CIC | c.2336C>A p.P779H | Missense Mutation (SNP) | VAF 22/508 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.953); called by muse, mutect2
- CILP2 | c.1694G>A p.S565N | Missense Mutation (SNP) | VAF 24/687 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2
- CKAP5 | c.6067del p.R2023Dfs*5 (on ENST00000529230 / NM_001008938.4; = p.R1963Dfs*5 on NM_014756.3) | Frame Shift Del (DEL) | VAF 64/279 reads (23%) | called by mutect2, varscan2
- CKMT2 | c.425C>T p.T142I | Missense Mutation (SNP) | VAF 86/317 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLGN | c.1622dup p.Q542Afs*3 | Frame Shift Ins (INS) | VAF 39/160 reads (24%) | called by mutect2, varscan2
- CMC2 | c.80del p.N27Ifs*5 | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | called by mutect2, pindel, varscan2
- CNNM1 | c.286del p.E96Rfs*138 | Frame Shift Del (DEL) | VAF 126/840 reads (15%) | called by mutect2, pindel, varscan2
- COL11A1 | c.2512G>T p.G838* | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- COL22A1 | c.4069G>T p.G1357* | Nonsense Mutation (SNP) | VAF 81/424 reads (19%) | called by muse, mutect2, varscan2
- CPLANE1 | c.9279del p.K3093Nfs*16 | Frame Shift Del (DEL) | VAF 73/453 reads (16%) | called by mutect2, pindel, varscan2
- CRCT1 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 22/451 reads (5%) | PolyPhen benign (0.157); called by muse, mutect2
- CRTAC1 | c.1215A>G p.T405= | Splice Region (SNP) | VAF 74/403 reads (18%) | called by muse, mutect2, varscan2
- CRYBG3 | c.3158del p.L1053* | Frame Shift Del (DEL) | VAF 28/146 reads (19%) | called by mutect2, pindel, varscan2
- CSMD1 | c.7537A>C p.T2513P (on ENST00000520002; = p.T2512P on NM_033225.6) | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- CTCF | c.866C>T p.T289I | Missense Mutation (SNP) | VAF 103/394 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CTDP1 | c.257A>G p.E86G | Missense Mutation (SNP) | VAF 135/595 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- CTDSP1 | c.680A>G p.D227G | Missense Mutation (SNP) | VAF 84/358 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- CTNNA2 | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CTSA | c.1101C>G p.N367K | Missense Mutation (SNP) | VAF 83/406 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- CXXC4 | c.350del p.G117Vfs*98 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, varscan2
- CYLD | c.2165del p.N722Mfs*13 | Frame Shift Del (DEL) | VAF 41/177 reads (23%) | called by mutect2, pindel, varscan2
- CYP2A13 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 116/494 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- CYP4F22 | c.257A>G p.K86R | Missense Mutation (SNP) | VAF 65/313 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- DCAF4L2 | c.943T>A p.S315T | Missense Mutation (SNP) | VAF 18/409 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.232); called by muse, mutect2
- DCAF8L2 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 140/596 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, varscan2
- DCHS1 | c.4821G>T p.L1607F | Missense Mutation (SNP) | VAF 107/413 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DCHS2 | c.1128G>T p.Q376H | Missense Mutation (SNP) | VAF 111/512 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DCLK1 | c.747dup p.G250Wfs*2 | Frame Shift Ins (INS) | VAF 48/217 reads (22%) | called by mutect2, pindel, varscan2
- DDX10 | c.901del p.I301* | Frame Shift Del (DEL) | VAF 53/284 reads (19%) | called by mutect2, pindel, varscan2
- DDX42 | c.2430_2431del p.T811* | Frame Shift Del (DEL) | VAF 74/414 reads (18%) | called by pindel, varscan2
- DEGS1 | c.871A>G p.N291D | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DENND4C | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEPDC5 | c.3458A>G p.Y1153C (on ENST00000400246; = p.Y1222C on NM_014662.5) | Missense Mutation (SNP) | VAF 92/371 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DGKD | c.1288del p.Q430Rfs*82 (on ENST00000264057 / NM_152879.3; = p.Q386Rfs*82 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 105/443 reads (24%) | called by mutect2, pindel, varscan2
- DGKQ | c.2518C>T p.P840S | Missense Mutation (SNP) | VAF 126/485 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHRS9 | c.147dup p.D50* | Frame Shift Ins (INS) | VAF 88/450 reads (20%) | called by mutect2, pindel, varscan2
- DIP2A | c.3625_3626del p.C1209Qfs*134 | Frame Shift Del (DEL) | VAF 56/284 reads (20%) | called by pindel, varscan2
- DIP2C | c.3107dup p.G1037Rfs*56 | Frame Shift Ins (INS) | VAF 56/329 reads (17%) | called by mutect2, pindel, varscan2
- DIS3L | c.636G>T p.E212D (on ENST00000319212 / NM_001143688.3; = p.E129D on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/335 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- DMRTA2 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 106/539 reads (20%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- DNAH17 | c.7094A>G p.Q2365R | Missense Mutation (SNP) | VAF 119/439 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DNAH5 | c.11500C>T p.R3834C | Missense Mutation (SNP) | VAF 59/337 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- DNAJC2 | c.1738del p.I580* | Frame Shift Del (DEL) | VAF 67/437 reads (15%) | called by mutect2, pindel, varscan2
- DNHD1 | c.1585del p.C529Vfs*12 | Frame Shift Del (DEL) | VAF 98/456 reads (21%) | called by mutect2, pindel, varscan2
- DNHD1 | c.12661G>T p.A4221S | Missense Mutation (SNP) | VAF 68/285 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- DNHD1 | c.13406C>T p.P4469L | Missense Mutation (SNP) | VAF 118/535 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- DPM1 | c.371A>G p.H124R | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DPYSL3 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 126/553 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- DRD3 | c.382A>G p.R128G | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSC2 | c.2089A>G p.I697V | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- DTD2 | c.147del p.F49Lfs*17 | Frame Shift Del (DEL) | VAF 60/283 reads (21%) | called by mutect2, pindel, varscan2
- DXO | c.1032G>T p.Q344H | Missense Mutation (SNP) | VAF 22/556 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.342); called by muse, mutect2
- DYNC1H1 | c.12276-1G>T p.X4092_splice | Splice Site (SNP) | VAF 84/318 reads (26%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.6302G>A p.C2101Y | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EBF3 | c.833del p.G278Vfs*6 (on ENST00000355311 / NM_001375392.1; = p.G269Vfs*6 on NM_001005463.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 99/548 reads (18%) | called by mutect2, pindel, varscan2
- EEA1 | c.771del p.K257Nfs*13 | Frame Shift Del (DEL) | VAF 35/176 reads (20%) | called by mutect2, pindel, varscan2
- EIF3G | c.328T>C p.F110L | Missense Mutation (SNP) | VAF 20/514 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.039); called by muse, mutect2
- ENTR1 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 58/507 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPB41L5 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EPG5 | c.2783A>G p.Q928R | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- EPHX4 | c.1083del p.D362Ifs*12 | Frame Shift Del (DEL) | VAF 25/144 reads (17%) | called by mutect2, pindel, varscan2
- ERC2 | c.2266A>G p.R756G | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ERCC1 | c.403A>C p.S135R | Missense Mutation (SNP) | VAF 80/326 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ERF | c.121_123del p.E41del | In Frame Del (DEL) | VAF 82/422 reads (19%) | called by pindel, varscan2
- ERLEC1 | c.1271C>T p.T424I | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ESPN | c.1355dup p.P453Tfs*16 | Frame Shift Ins (INS) | VAF 62/250 reads (25%) | called by mutect2, varscan2
- ETFA | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 112/465 reads (24%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- EYS | c.5100del p.K1700Nfs*3 | Frame Shift Del (DEL) | VAF 35/174 reads (20%) | called by mutect2, pindel, varscan2
- FADD | c.403del p.R135Afs*3 | Frame Shift Del (DEL) | VAF 85/461 reads (18%) | called by mutect2, pindel, varscan2
- FAHD2A | c.749A>C p.N250T | Missense Mutation (SNP) | VAF 100/373 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- FAM160A2 | c.1828del p.E610Rfs*52 (on ENST00000449352 / NM_001098794.2; = p.E624Rfs*52 on NM_032127.4) | Frame Shift Del (DEL) | VAF 77/383 reads (20%) | called by mutect2, pindel, varscan2
- FAM172A | c.344del p.K115Rfs*5 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- FAM184B | c.551A>G p.K184R | Missense Mutation (SNP) | VAF 118/555 reads (21%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- FAM209A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 70/295 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
844 further variants in this file (454 protein-altering or splice-affecting, 338 silent, 52 other) are not listed here.
